Gene-level copy-number profile of tumor specimen ALCH-AE2Q-TTP1-A from ALCHEMIST case ALCH-AE2Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,015 days).
Specimen ALCH-AE2Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 622d6912-d102-4ca3-9919-a2f35a08b12f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE2Q-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/e30fc5e3-e43b-4f0b-aa4d-5a984e932f4f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 3,425; copy number 2: 53,989; copy number 3: 829; copy number 4: 52; copy number 5: 5; copy number 6: 3; copy number 9: 6; copy number 10: 1; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,644,544–25,659,111, 1 gene (within-gene range 0–2): AL031280.1.
- chr1:53,062,052–53,085,502, 3 genes: PODN, AL445183.1, HIGD1AP11.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr4:183,380,345–183,381,705, 1 gene: AC093844.1.
- chr6:57,919,912–57,961,382, 1 gene (within-gene range 0–2): AL021368.4.
- chr6:57,946,074–57,961,501, 1 gene: LINC00680.
- chr7:56,875,385–56,882,146, 1 gene: AC118758.1.
- chr8:142,620,373–142,621,064, 1 gene: AP006547.1.
- chr9:35,749,287–35,758,585, 3 genes (within-gene range 0–2): RGP1, MSMP, AL133410.2.
- chr9:121,444,991–121,520,424, 3 genes (within-gene range 0–2): GGTA1, RN7SL187P, HMGB1P37.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–2): AL357936.1.
- chr10:8,050,450–8,053,484, 2 genes: GATA3-AS1, AL390294.1.
- chr11:77,034,398–77,041,973, 1 gene: B3GNT6.
- chr11:128,934,731–128,943,399, 1 gene: TP53AIP1.
- chr11:134,378,504–134,412,242, 1 gene: B3GAT1.
- chr12:113,291,523–113,291,608, 1 gene (within-gene range 0–2): MIR6762.
- chr15:25,174,927–25,249,279, 41 genes (within-gene range 0–2): SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43.
- chr17:16,342,534–16,353,656, 1 gene (within-gene range 0–2): CENPV.
- chr17:29,071,122–29,180,398, 3 genes (within-gene range 0–2): MYO18A, TIAF1, AC024619.3.
- chr19:36,489,649–36,498,159, 2 genes (within-gene range 0–2): AC092295.2, CTBP2P7.
- chr19:55,214,287–55,230,279, 4 genes (within-gene range 0–2): AC010327.7, AC010327.5, TMEM86B, AC010327.6.
- chr19:55,230,885–55,230,952, 1 gene (within-gene range 0–2): MIR6804.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:41,872,747–41,882,955, 1 gene, copy number 5: LINC00682.
- chr7:37,032–37,477, 1 gene, copy number 6: AC215522.1.
- chr11:86,649–207,428, 9 genes, copy number 5–9 (within-gene range 2–9): OR4F2P, AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P, BET1L, SCGB1C1, ODF3.
- chr15:28,575,019–28,579,400, 1 gene, copy number 10: HERC2P11.
- chr20:63,005,927–63,007,035, 1 gene, copy number 5: BHLHE23.
- chr21:43,446,601–43,479,534, 3 genes, copy number 6–13: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 2,172. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
